Somatic mutation profile of tumor specimen C3L-05477-01 (aliquot CPT0418260006) from CPTAC case C3L-05477, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 67.8 years (24,756 days).
Specimen C3L-05477-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf4b70e3-cd1c-4727-9afe-e605e03f575a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05477-31 (Blood Derived Normal), aliquot CPT0419880004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7fcb9cb-685f-4deb-917a-7607abe7e1fd

The open-access MAF lists 149 somatic variants for this specimen: 101 protein-altering or splice-affecting, 43 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 43, Nonsense Mutation 5, Frame Shift Del 3, 3'UTR 1, RNA 1, 5'UTR 1, Splice Region 1, Nonstop Mutation 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3186_3187del p.S1063* | Frame Shift Del (DEL) | VAF 87/164 reads (53%) | catalogued as rs1060503362; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 112/343 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6380del p.K2127Sfs*7 (on ENST00000272895 / NM_173076.3; = p.K1809Sfs*7 on NM_015657.3) | Frame Shift Del (DEL) | VAF 38/132 reads (29%) | catalogued as rs1559112599; called by mutect2, pindel, varscan2
- ADSS1 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs928510188; called by muse, mutect2, varscan2
- ATP6V1D | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53598983; called by muse, mutect2, varscan2
- BORA | c.866G>A p.G289E (on ENST00000613797; = p.G214E on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64695180; called by muse, mutect2, varscan2
- CNTN3 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55165405; called by muse, mutect2, varscan2
- DIPK1C | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as rs536902218; called by muse, mutect2, varscan2
- EYS | c.4172C>A p.T1391N | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs1223812574; called by muse, mutect2
- H6PD | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 85/461 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1268620316, COSV66230416; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.333); catalogued as COSV54561659; called by muse, mutect2, varscan2
- HTR1A | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60501913; called by muse, mutect2, varscan2
- INHA | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 64/392 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs750783756, COSV54713144; called by muse, varscan2
- KCNU1 | c.3450G>C p.*1150Yext*21 | Nonstop Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as COSV67759944, COSV67760062; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.115); catalogued as rs887839808; called by muse, varscan2
- MMEL1 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.294); catalogued as rs144887855; called by muse, mutect2, varscan2
- MUC16 | c.32477C>T p.T10826M | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs759594403, COSV67496608; called by muse, mutect2, varscan2
- NKX2-4 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 81/471 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs370549869; called by muse, mutect2, varscan2
- NUP155 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 89/586 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs755278532; called by muse, mutect2, varscan2
- OPRM1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as rs1259264846; called by muse, mutect2, varscan2
- OR10A4 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs763641603, COSV65842061; called by muse, mutect2
- OR52E4 | c.315T>G p.F105L | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV100389238; called by muse, mutect2
- PCDHA1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 57/538 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as rs1562134332, COSV100974246, COSV65374996; called by muse, varscan2
- PCDHA2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV65364468; called by muse, mutect2
- PKDREJ | c.5109C>G p.I1703M | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs138759688; called by muse, mutect2, varscan2
- PLCD4 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.179); catalogued as COSV68842286; called by muse, mutect2
- PTCHD4 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs191919500, COSV100260253; called by muse, mutect2
- RBMS3 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1421332978, COSV56148034; called by muse, mutect2
- RGL2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs775447080; called by muse, mutect2, varscan2
- RHBDF2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as rs554709470, COSV100489682; called by muse, mutect2, varscan2
- SEC14L1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs575025415, COSV66726165; called by muse, mutect2, varscan2
- SEPHS2 | c.1001G>C p.R334T | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV101529329; called by muse, mutect2, varscan2
- SEPHS2 | c.179G>A p.Sec60* | Nonsense Mutation (SNP) | VAF 97/417 reads (23%) | catalogued as COSV101529349; called by muse, mutect2, varscan2
- SI | c.3538A>C p.T1180P | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV52266457; called by muse, mutect2, varscan2
- SI | c.3499T>A p.L1167I | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100014645, COSV52303947; called by muse, mutect2
- SLC44A2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs370647260; called by muse, mutect2, varscan2
- SLC4A2 | c.2455G>A p.V819I | Missense Mutation (SNP) | VAF 31/477 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs752526026, COSV52540031; called by muse, mutect2
- SPATA31D1 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 110/473 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV61195107; called by muse, varscan2
- SSTR4 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 130/666 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372339309; called by muse, mutect2, varscan2
- TAF6L | c.1775C>G p.S592W | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV53668464, COSV53670261; called by muse, mutect2, varscan2
- TOX2 | c.610G>A p.G204R (on ENST00000358131 / NM_001098798.2; = p.G153R on NM_032883.3) | Missense Mutation (SNP) | VAF 138/618 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57889007; called by muse, mutect2, varscan2
- TP53 | c.989T>A p.L330H | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52677086, COSV52758102, COSV52857788, COSV53683887; called by muse, mutect2, varscan2
- TRPM3 | c.1768C>T p.R590C (on ENST00000357533 / NM_001366142.2; = p.R423C on NM_020952.6) | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62579961; called by muse, mutect2, varscan2
- TUSC1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs773702120; called by muse, mutect2, varscan2
- URB2 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV50989091; called by muse, mutect2, varscan2
- WDR90 | c.2728G>A p.V910M | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs746408479, COSV104395989; called by muse, mutect2, varscan2
- ZNF560 | c.2348G>A p.R783H | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs751597194; called by muse, mutect2, varscan2
- A1CF | c.1237G>A p.V413I (on ENST00000373993 / NM_138932.2; = p.V405I on NM_014576.4) | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ALG10 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2
- ANKRD36C | c.2038A>G p.T680A | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- BCKDK | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- BCL9 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 146/258 reads (57%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BPTF | c.8654G>A p.C2885Y | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALCOCO2 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 46/296 reads (16%) | called by muse, mutect2, varscan2
- CASZ1 | c.2561C>G p.S854C | Missense Mutation (SNP) | VAF 162/359 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CCER1 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CEP89 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CP | c.2734A>T p.R912W | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2
- CYLC1 | c.1175A>G p.K392R | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CYLC2 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- DCX | c.830A>T p.N277I | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DYNAP | c.281C>A p.S94* (on ENST00000321600; = p.S68* on NM_173629.3) | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | called by mutect2, varscan2
- EDIL3 | c.459T>A p.N153K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- FAM135B | c.2031G>T p.K677N | Missense Mutation (SNP) | VAF 75/524 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- FCHSD2 | c.1358T>G p.M453R | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- GNAI1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.02); called by muse, mutect2
- HDHD5 | c.505A>T p.M169L (on ENST00000336737 / NM_033070.3; = p.M139L on NM_017829.5) | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- INF2 | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by muse, mutect2
- KIF3B | c.1794A>C p.K598N | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- KMO | c.1066A>T p.I356F | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- KRTAP25-1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LAMB1 | c.38-5C>T | Splice Region (SNP) | VAF 20/512 reads (4%) | called by muse, mutect2
- MAIP1 | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAML3 | c.1597A>C p.T533P | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0); called by mutect2, varscan2
- MBIP | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2
- NCAPD3 | c.3637G>C p.E1213Q | Missense Mutation (SNP) | VAF 106/327 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NOL8 | c.2475G>C p.E825D | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- PAPOLG | c.167A>C p.E56A | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PDCD1 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLB1 | c.3851G>A p.S1284N | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRKCD | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 25/250 reads (10%) | called by muse, mutect2, varscan2
- PTPN22 | c.1660C>A p.P554T (on ENST00000359785 / NM_001193431.2; = p.P499T on NM_012411.5) | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PTPRN | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RBM15B | c.155G>C p.R52P | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- RNF150 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RNPS1 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RPS27 | c.159_166del p.V54Cfs*33 | Frame Shift Del (DEL) | VAF 30/238 reads (13%) | called by mutect2, pindel, varscan2
- SGF29 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 173/417 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SIM1 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK5 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- SNTG2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN5 | c.5432G>A p.R1811K | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SRCAP | c.3604G>C p.G1202R | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TAF6L | c.1576C>G p.R526G | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TBKBP1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- THBS4 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 63/212 reads (30%) | called by muse, mutect2, varscan2
- TTC37 | c.3062T>G p.V1021G | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF189 | c.714A>C p.K238N | Missense Mutation (SNP) | VAF 89/321 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ZNF28 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ZNF880 | c.1123A>C p.T375P | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2
- ZSWIM3 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 67/645 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADARB2 | c.1944G>A p.L648= | Silent (SNP) | VAF 250/469 reads (53%) | catalogued as rs1331793595; called by muse, mutect2, varscan2
- ADCY5 | c.1263G>A p.S421= | Silent (SNP) | VAF 47/242 reads (19%) | catalogued as rs145186295; called by muse, varscan2
- AMDHD2 | c.1209G>A p.Q403= (on ENST00000293971 / NM_001330449.2; = p.Q433= on NM_015944.4) | Silent (SNP) | VAF 38/388 reads (10%) | called by muse, mutect2
- BBS7 | c.1320C>T p.F440= | Silent (SNP) | VAF 48/184 reads (26%) | called by muse, mutect2, varscan2
- BCOR | c.3348C>T p.P1116= | Silent (SNP) | VAF 163/258 reads (63%) | catalogued as rs756729524, COSV100653012; called by muse, mutect2, varscan2
- C17orf113 | c.72C>T p.N24= | Silent (SNP) | VAF 79/266 reads (30%) | catalogued as rs138910547; called by muse, mutect2, varscan2
- COL4A3 | c.4341C>A p.V1447= | Silent (SNP) | VAF 100/288 reads (35%) | catalogued as COSV101170310; called by mutect2, varscan2
- DDX24 | c.2367G>A p.K789= | Silent (SNP) | VAF 53/408 reads (13%) | called by muse, mutect2, varscan2
- DUSP7 | c.597G>A p.S199= | Silent (SNP) | VAF 98/354 reads (28%) | catalogued as rs1164582453, COSV56588588; called by muse, varscan2
- FAM47A | c.1131G>A p.A377= | Silent (SNP) | VAF 55/265 reads (21%) | catalogued as rs767427711, COSV60493997, COSV60498400; called by muse, mutect2, varscan2
- IRX1 | c.885C>A p.R295= | Silent (SNP) | VAF 106/950 reads (11%) | called by muse, mutect2, varscan2
- KIF7 | c.600C>T p.N200= | Silent (SNP) | VAF 50/338 reads (15%) | called by muse, varscan2
- KRT72 | c.201C>T p.G67= | Silent (SNP) | VAF 40/514 reads (8%) | catalogued as rs1206714714; called by muse, mutect2
- LPA | c.2463T>A p.P821= | Silent (SNP) | VAF 38/365 reads (10%) | called by muse, mutect2, varscan2
- MAK | c.123T>C p.S41= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- MAP9 | c.1701G>A p.K567= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV60907169; called by muse, mutect2, varscan2
- MED23 | c.2955G>A p.E985= | Silent (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- MRGPRE | c.786C>T p.C262= | Silent (SNP) | VAF 385/643 reads (60%) | catalogued as rs576704362; called by muse, mutect2, varscan2
- MYO10 | c.1380G>A p.E460= | Silent (SNP) | VAF 62/409 reads (15%) | catalogued as rs773631804; called by muse, mutect2, varscan2
- MYO15B | c.7671C>T p.A2557= | Silent (SNP) | VAF 128/420 reads (30%) | catalogued as rs1011511596, COSV101640077; called by muse, mutect2, varscan2
- NDC80 | c.1809G>A p.Q603= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV55246877; called by muse, mutect2, varscan2
- NEB | c.12405C>T p.A4135= | Silent (SNP) | VAF 66/288 reads (23%) | called by muse, mutect2, varscan2
- NOL11 | c.2118T>C p.N706= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs1334777692; called by muse, mutect2, varscan2
- NXPH2 | c.555C>T p.F185= | Silent (SNP) | VAF 23/334 reads (7%) | called by muse, mutect2
- OR14I1 | c.330G>T p.L110= | Silent (SNP) | VAF 120/266 reads (45%) | called by muse, mutect2, varscan2
- PMS2 | c.2034C>T p.I678= | Silent (SNP) | VAF 21/225 reads (9%) | catalogued as COSV99764400; called by muse, mutect2, varscan2
- POLD1 | c.1422C>T p.L474= | Silent (SNP) | VAF 17/264 reads (6%) | catalogued as rs369332787; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PRL | c.552G>A p.L184= | Silent (SNP) | VAF 17/366 reads (5%) | called by muse, mutect2
- PTGER4 | c.774G>A p.R258= | Silent (SNP) | VAF 42/924 reads (5%) | called by muse, mutect2
- RTL1 | c.2541C>T p.V847= | Silent (SNP) | VAF 84/357 reads (24%) | catalogued as rs1033103141; called by muse, mutect2, varscan2
- SLCO5A1 | c.324C>T p.S108= | Silent (SNP) | VAF 69/607 reads (11%) | called by muse, mutect2, varscan2
- SSRP1 | c.1357T>C p.L453= | Silent (SNP) | VAF 95/251 reads (38%) | called by muse, mutect2, varscan2
- TF | c.93G>A p.S31= | Silent (SNP) | VAF 56/323 reads (17%) | catalogued as rs1291195506, COSV99395316; called by muse, mutect2, varscan2
- TFAP4 | c.741C>T p.H247= | Silent (SNP) | VAF 62/329 reads (19%) | called by muse, mutect2, varscan2
- TFPI | c.414T>C p.I138= | Silent (SNP) | VAF 90/258 reads (35%) | called by muse, mutect2, varscan2
- UBA6 | c.24C>T p.A8= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs766047688, COSV59179524; called by muse, mutect2
- URB1 | c.6789C>T p.D2263= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as rs995583741; called by muse, mutect2
- YWHAZ | c.672C>T p.N224= | Silent (SNP) | VAF 44/287 reads (15%) | called by muse, mutect2, varscan2
- ZFHX2 | c.1533C>T p.D511= | Silent (SNP) | VAF 27/355 reads (8%) | catalogued as rs755931087; called by muse, mutect2
- ZNF236 | c.1599C>T p.T533= | Silent (SNP) | VAF 74/291 reads (25%) | catalogued as rs779896368, COSV53489192; called by muse, mutect2, varscan2
- ZNF516 | c.1101C>A p.A367= | Silent (SNP) | VAF 99/346 reads (29%) | called by muse, mutect2, varscan2
- ZNF787 | c.666G>T p.G222= | Silent (SNP) | VAF 40/471 reads (8%) | called by muse, mutect2
- ZNF99 | c.1938G>A p.E646= | Silent (SNP) | VAF 44/292 reads (15%) | catalogued as COSV101233610; called by muse, varscan2
- GLOD4 | chr17:783248 G>C | 5'Flank (SNP) | VAF 28/282 reads (10%) | called by muse, mutect2
- KCNK12 | c.*8540C>T | 3'UTR (SNP) | VAF 70/367 reads (19%) | catalogued as rs760339460; called by muse, mutect2, varscan2
- LINC02269 | n.556C>T | RNA (SNP) | VAF 59/235 reads (25%) | called by muse, mutect2, varscan2
- PRR12 | c.52-503C>G | Intron (SNP) | VAF 80/424 reads (19%) | called by muse, mutect2, varscan2
- SNX13 | c.-142G>A | 5'UTR (SNP) | VAF 115/589 reads (20%) | catalogued as rs559554797; called by muse, mutect2, varscan2
